Somatic mutation profile of tumor specimen TCGA-NJ-A4YG-01A (aliquot TCGA-NJ-A4YG-01A-22D-A25L-08) from TCGA case TCGA-NJ-A4YG, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.2 years (23,812 days).
Specimen TCGA-NJ-A4YG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31d384da-0ab2-4dd8-ac9e-cf5173df8a7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NJ-A4YG-10A (Blood Derived Normal), aliquot TCGA-NJ-A4YG-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fef0254b-58ac-4c65-b83b-d862beb6ce47

The open-access MAF lists 164 somatic variants for this specimen: 127 protein-altering or splice-affecting, 35 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 35, Nonsense Mutation 9, Frame Shift Ins 3, In Frame Del 2, Frame Shift Del 1, Splice Site 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.8431C>A p.Q2811K | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101446771, COSV101447101; called by muse, mutect2
- AC006059.2 | c.1989G>T p.K663N | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV100045788; called by muse, mutect2, varscan2
- ACTN4 | c.2619dup p.D874Rfs*17 | Frame Shift Ins (INS) | VAF 13/57 reads (23%) | catalogued as rs869292397; called by mutect2, pindel, varscan2
- AHCYL2 | c.1333A>G p.I445V | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100273605; called by muse, mutect2, varscan2
- AKAP6 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs758792601, COSV99802941; called by muse, mutect2, varscan2
- ANKRD30A | c.3042G>C p.E1014D (on ENST00000611781; = p.E958D on NM_052997.2) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV100654410; called by muse, mutect2
- ARHGEF12 | c.3434C>T p.P1145L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100755099; called by muse, mutect2, varscan2
- ASCC3 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100226112; called by muse, mutect2, varscan2
- ASGR2 | c.627C>A p.N209K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs139922820, COSV99643118; called by muse, mutect2, varscan2
- ASH1L | c.6568G>C p.E2190Q (on ENST00000368346 / NM_001366177.2; = p.E2185Q on NM_018489.3) | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as COSV64207354; called by muse, mutect2
- BCLAF1 | c.1679A>G p.N560S | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.822); catalogued as COSV100786818; called by muse, mutect2
- CACNA1C | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs533892755, COSV59698705; ClinVar: uncertain significance; called by muse, mutect2
- CAPZA3 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99856690; called by muse, mutect2, varscan2
- CASZ1 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.463); catalogued as COSV100681882; called by muse, mutect2, varscan2
- CAV1 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV100591989; called by muse, mutect2, varscan2
- CBX2 | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV99490964; called by muse, mutect2, varscan2
- CDK14 | c.589C>T p.H197Y (on ENST00000380050 / NM_001287135.2; = p.H179Y on NM_012395.3) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99726345; called by muse, mutect2
- CILP | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99973751; called by muse, mutect2
- COG7 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV100207710; called by muse, mutect2
- CRHBP | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV99169513; called by muse, mutect2, varscan2
- CXorf66 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.882); catalogued as rs936980173, COSV65168887; called by muse, mutect2
- DDIAS | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100231107, COSV100231348, COSV100231434; called by muse, mutect2
- DNAH8 | c.6633G>T p.W2211C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100542944, COSV59433572; called by muse, mutect2
- DOK6 | c.532A>T p.M178L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV101234825; called by muse, mutect2, varscan2
- DSE | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV100528705, COSV59063270; called by muse, mutect2, varscan2
- DTX3 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99678171; called by muse, mutect2, varscan2
- ECD | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100881475; called by muse, mutect2, varscan2
- ELAPOR2 | c.1525G>A p.E509K (on ENST00000450689 / NM_001142749.3; = p.E342K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV99789199; called by muse, mutect2
- ELL2 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99427723; called by muse, mutect2, varscan2
- EPSTI1 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV58045058; called by muse, mutect2, varscan2
- ERBIN | c.4043G>A p.R1348K (on ENST00000284037 / NM_001253697.2; = p.R1307K on NM_018695.4) | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV99397512; called by muse, mutect2
- EXPH5 | c.3050C>G p.T1017R | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99761982; called by muse, mutect2, varscan2
- FAM110B | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV100826224; called by muse, mutect2
- FAM135B | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as rs1216473189, COSV99357777; called by muse, mutect2, varscan2
- FRMPD2 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV100564046; called by muse, varscan2
- GPR162 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs781975870, COSV50591407; called by muse, mutect2
- GRIN2A | c.692G>C p.C231S | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1238779318, CM138228, COSV100410554; called by muse, mutect2, varscan2
- H2AC15 | c.360A>T p.K120N | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as COSV100357047; called by muse, mutect2
- H2AX | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.429); catalogued as COSV99598121; called by muse, mutect2, varscan2
- HECTD3 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99870356; called by muse, mutect2, varscan2
- HOXA1 | c.838C>G p.R280G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547406, COSV58029360; called by muse, mutect2, varscan2
- HOXB13 | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99284908; called by muse, mutect2, varscan2
- IFNG | c.378G>T p.L126F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV99971227; called by muse, mutect2, varscan2
- IL18R1 | c.1265G>C p.G422A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52124156, COSV99295375; called by muse, mutect2, varscan2
- JRK | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.348); catalogued as rs368512461; called by muse, mutect2
- KCNA4 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs761300035, COSV100069156; called by muse, mutect2, varscan2
- KCTD18 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100728928; called by muse, mutect2, varscan2
- KIFC3 | c.951C>A p.Y317* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV101109291; called by muse, mutect2
- KLF11 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100007713, COSV100007842; called by muse, mutect2, varscan2
- KLF17 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs144146386; called by mutect2, varscan2
- KRT16 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 41/224 reads (18%) | catalogued as COSV100053001; called by muse, mutect2, varscan2
- LSG1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99503406; called by muse, mutect2
- MCOLN2 | c.1363T>C p.C455R | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs952875957; called by muse, mutect2
- MDM1 | c.840G>C p.E280D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV100292004; called by muse, mutect2, varscan2
- MPZL3 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV99636442; called by muse, mutect2, varscan2
- MUC16 | c.21677C>G p.S7226* | Nonsense Mutation (SNP) | VAF 29/242 reads (12%) | catalogued as COSV101200634; called by muse, mutect2, varscan2
- MUC16 | c.8422T>G p.S2808A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV101200635; called by muse, mutect2, varscan2
- MYH8 | c.5125C>A p.L1709I | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV101238564; called by muse, mutect2, varscan2
- MYOM2 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs773090655, COSV50703228; called by muse, mutect2, varscan2
- NEU4 | c.157C>T p.R53C (on ENST00000391969 / NM_001167602.3; = p.R65C on NM_080741.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.189); catalogued as rs756172984, COSV100372155; called by muse, mutect2
- NIPBL | c.1969A>T p.R657* | Nonsense Mutation (SNP) | VAF 27/112 reads (24%) | catalogued as COSV99241899; called by muse, mutect2, varscan2
- NOTCH4 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 13/146 reads (9%) | catalogued as COSV100900849; called by muse, mutect2
- NUP155 | c.1600G>C p.E534Q (on ENST00000231498 / NM_153485.3; = p.E475Q on NM_004298.4) | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV99193976; called by muse, mutect2
- OCEL1 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1470153364, COSV99285784; called by mutect2, varscan2
- OFD1 | c.2560G>T p.A854S | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV100407047; called by muse, mutect2, varscan2
- OR10Z1 | c.864T>G p.I288M | Missense Mutation (SNP) | VAF 56/448 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV100779058; called by muse, mutect2, varscan2
- OR2T6 | c.432C>G p.I144M | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.1); catalogued as rs1406912430, COSV100861605; called by muse, mutect2, varscan2
- OR4K13 | c.281G>T p.W94L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100237825; called by muse, mutect2
- OR7G3 | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | catalogued as COSV59640595; called by muse, mutect2
- ORC3 | c.612G>C p.R204S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV100006149; called by muse, mutect2, varscan2
- PCDHGA9 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.028); catalogued as COSV99543204; called by muse, mutect2
- PFKL | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62464533; called by muse, mutect2
- PIK3R2 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs747444256, COSV99717613; called by muse, mutect2, varscan2
- PITPNM1 | c.3539C>T p.S1180L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs894148416, COSV99653773; called by muse, mutect2, varscan2
- PLA2G6 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs121908685, CM063030, COSV59267862; called by muse, mutect2
- PXDNL | c.1124G>T p.R375M | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.53); catalogued as COSV100685271; called by muse, mutect2, varscan2
- RBM12 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as COSV100467851, COSV100468279; called by muse, mutect2, varscan2
- RFX4 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100774756; called by muse, mutect2
- RIMS2 | c.2164G>A p.D722N (on ENST00000666250 / NM_001348490.2; = p.D530N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV99163578; called by muse, mutect2, varscan2
- RUFY3 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99887676; called by muse, mutect2
- RYR2 | c.1646C>A p.A549D | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as CM097928, COSV100772061, COSV63670037; called by muse, mutect2, varscan2
- RYR2 | c.2096C>A p.S699Y | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.686); catalogued as COSV100772062; called by muse, mutect2
- RYR3 | c.5922G>T p.Q1974H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV101213467; called by muse, mutect2, varscan2
- SEMA5A | c.2549G>A p.W850* | Nonsense Mutation (SNP) | VAF 8/89 reads (9%) | catalogued as COSV66793525; called by muse, mutect2
- SHOC2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.152); catalogued as COSV99510391; called by muse, mutect2
- SIX4 | c.2270A>G p.E757G | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.057); catalogued as COSV99382411; called by muse, mutect2, varscan2
- SLC17A4 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100930650; called by muse, mutect2, varscan2
- SLC34A2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1268215258, COSV101158444; called by muse, mutect2, varscan2
- SLITRK3 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as COSV99579739; called by muse, mutect2, varscan2
- SPHKAP | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200013987, COSV60888529; called by muse, mutect2, varscan2
- SPNS2 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV100223767; called by muse, mutect2
- STAT4 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1481899244, COSV100636127; called by muse, mutect2
- STIL | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99681182; called by muse, mutect2, varscan2
- STIM1 | c.270+1G>T p.X90_splice | Splice Site (SNP) | VAF 22/100 reads (22%) | catalogued as COSV100330910; called by muse, mutect2, varscan2
- STON1 | c.1799G>C p.R600P | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV100562086, COSV59132285; called by muse, mutect2, varscan2
- TAL1 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99596267; called by muse, mutect2, varscan2
- TENM2 | c.950A>G p.H317R (on ENST00000518659 / NM_001122679.2; = p.H126R on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV101319245; called by muse, mutect2
- THSD7A | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV101448825, COSV70273681; called by muse, mutect2, varscan2
- TLR4 | c.1764G>T p.Q588H (on ENST00000355622 / NM_138554.5; = p.Q548H on NM_003266.4) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV100842824; called by muse, mutect2, varscan2
- TPGS2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100528885; called by muse, mutect2
- TRPV5 | c.1897G>T p.V633F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs767160383, COSV54688409, COSV99520835; called by muse, mutect2, varscan2
- TXNDC9 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.34); catalogued as COSV99959978; called by muse, mutect2
- UBAP2 | c.2914C>T p.Q972* | Nonsense Mutation (SNP) | VAF 13/191 reads (7%) | catalogued as COSV99602394; called by muse, mutect2
- USH2A | c.7775C>A p.P2592Q | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100239394; called by muse, mutect2
- VPS45 | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64886996; called by muse, mutect2
- WDR33 | c.3586C>T p.R1196C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as rs959245891, COSV59252722; called by muse, mutect2, varscan2
- WTAP | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61610446, COSV61610540; called by muse, mutect2
- XIRP2 | c.8474C>G p.A2825G (on ENST00000628543; = p.A3000G on NM_152381.6) | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99745728, COSV99747575; called by muse, mutect2, varscan2
- XPNPEP1 | c.1858C>G p.L620V | Missense Mutation (SNP) | VAF 18/457 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100451081; called by muse, mutect2
- XRCC5 | c.740G>T p.W247L | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101079758; called by muse, mutect2, varscan2
- YY1 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99216926; called by muse, mutect2
- ZFHX4 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50690943, COSV99265802; called by muse, mutect2
- ZNF395 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.668); catalogued as COSV100734040; called by muse, mutect2, varscan2
- ZNF536 | c.3403C>A p.P1135T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100835573; called by muse, mutect2, varscan2
- ZNF536 | c.3404C>A p.P1135H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.237); catalogued as COSV62817856; called by muse, mutect2, varscan2
- ZNF600 | c.1631A>C p.H544P | Missense Mutation (SNP) | VAF 27/373 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100593063, COSV57745775; called by muse, mutect2
- DYNC1LI1 | c.857_879del p.S286* | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel
- FNDC1 | c.2941_2955del p.P981_R985del | In Frame Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- IGKC | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- MAP3K10 | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- MASTL | c.1904_1933del p.M635_K644del | In Frame Del (DEL) | VAF 17/146 reads (12%) | called by mutect2, pindel
- NBEA | c.259A>T p.S87C | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PCDHA8 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 10/344 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); called by muse, mutect2
- RYR2 | c.11189_11190insT p.L3731Tfs*8 | Frame Shift Ins (INS) | VAF 9/88 reads (10%) | called by mutect2, pindel, varscan2
- TRIOBP | c.4621dup p.A1541Gfs*12 | Frame Shift Ins (INS) | VAF 17/105 reads (16%) | called by mutect2, pindel, varscan2
- BRINP1 | c.2082C>G p.L694= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as COSV99776394; called by muse, mutect2
- CLMN | c.1371G>A p.L457= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as COSV100112740; called by muse, mutect2
- CSMD1 | c.7512C>T p.N2504= (on ENST00000520002; = p.N2503= on NM_033225.6) | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs560104234, COSV59348504; called by muse, mutect2, varscan2
- DOK6 | c.531G>T p.V177= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV101234824; called by muse, mutect2, varscan2
- EGFLAM | c.1038T>A p.P346= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as COSV100380571; called by muse, mutect2, varscan2
- FAXC | c.129C>A p.I43= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV101067200; called by muse, mutect2, varscan2
- FCGR1A | c.87A>G p.P29= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs1553750489, COSV100977273, COSV64985541; called by mutect2, varscan2
- FILIP1L | c.2505C>T p.D835= (on ENST00000354552 / NM_182909.3; = p.D595= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/218 reads (21%) | catalogued as rs571128891, COSV100497196; called by muse, mutect2, varscan2
- HELZ | c.2601C>T p.R867= | Silent (SNP) | VAF 59/290 reads (20%) | catalogued as COSV100698948; called by muse, mutect2, varscan2
- JPH1 | c.486G>A p.S162= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100646701; called by muse, mutect2, varscan2
- KAT8 | c.1245C>A p.I415= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99571692; called by muse, mutect2
- KIN | c.420G>A p.Q140= | Silent (SNP) | VAF 12/210 reads (6%) | catalogued as COSV101092654; called by muse, mutect2
- LINGO2 | c.975G>T p.V325= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- MTA1 | c.408G>A p.S136= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs376000021; called by muse, mutect2, varscan2
- OGT | c.2541T>C p.F847= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV101035550; called by muse, mutect2, varscan2
- OR2W3 | c.501C>G p.P167= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV100831768, COSV64457522; called by muse, mutect2
- OR4C16 | c.318C>A p.G106= | Silent (SNP) | VAF 43/273 reads (16%) | catalogued as rs375303396, COSV100114039; called by muse, mutect2, varscan2
- OR4S2 | c.705C>A p.L235= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as COSV100412739; called by muse, mutect2, varscan2
- PACC1 | c.243C>T p.A81= | Silent (SNP) | VAF 17/225 reads (8%) | catalogued as rs140199700; called by muse, mutect2
- PCDHGA11 | c.234G>A p.V78= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99543206; called by muse, mutect2
- PLPP4 | c.471G>A p.T157= | Silent (SNP) | VAF 13/185 reads (7%) | catalogued as rs569831062, COSV64829244; called by muse, mutect2
- PMM2 | c.198T>C p.Y66= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs766583461, COSV99191169; called by muse, mutect2, varscan2
- PPP1R36 | c.972C>T p.L324= | Silent (SNP) | VAF 14/179 reads (8%) | catalogued as COSV100072762; called by muse, mutect2
- PRR35 | c.1386C>T p.D462= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs748884674, COSV99552200; called by mutect2, varscan2
- PRRC2B | c.3735C>T p.C1245= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs770584731, COSV61934509; called by mutect2, varscan2
- RGS14 | c.1233G>T p.P411= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101281734; called by muse, varscan2
- RYR2 | c.2097C>A p.S699= | Silent (SNP) | VAF 18/175 reads (10%) | catalogued as COSV100772063; called by muse, mutect2, varscan2
- SEL1L2 | c.1896C>A p.A632= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV53155835, COSV99533645; called by muse, mutect2, varscan2
- SLC22A9 | c.573C>A p.A191= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV99655261; called by muse, mutect2, varscan2
- SUGP2 | c.768C>A p.P256= | Silent (SNP) | VAF 25/157 reads (16%) | catalogued as COSV100432165; called by mutect2, varscan2
- SUPT6H | c.2553A>T p.A851= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100112623; called by muse, mutect2, varscan2
- TSPAN13 | c.18C>T p.F6= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100018157; called by muse, mutect2
- VNN1 | c.165G>T p.R55= | Silent (SNP) | VAF 26/178 reads (15%) | catalogued as COSV100907799; called by muse, mutect2, varscan2
- ZBTB49 | c.2259G>T p.A753= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100552535; called by muse, mutect2, varscan2
- ZNF502 | c.933G>T p.T311= | Silent (SNP) | VAF 50/302 reads (17%) | catalogued as COSV56072973, COSV99939805; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826220 C>A | 3'Flank (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- WASF3 | c.717-890C>T | Intron (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100099207; called by muse, mutect2
